Surgical pathology report (de-identified scan), TCGA case TCGA-15-1446, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Mayo Clinic - Rochester, specimen TCGA-15-1446-01A (Primary Tumor).

Final Diagnosis:

Brain, right frontal lobe, biopsy #1, and excisions #2 & 3: Astrocytoma, [REDACTED] grade 4 (of 4), WHO grade 4 (of 4) with fibrillary, gemistocytic, and small cell features, see comment.

Seen in consultation with [REDACTED]

Diagnosis Comment:

Immunoperoxidase studies were performed on paraffin sections of the frontal lobe biopsy #1 using antibodies directed against the following antigens: MIB-1. MIB-1 demonstrates approximately 40-60% of the cells to be positive, supporting the above diagnosis.

TCGA-15-1446

Preliminary Frozen Section Consultation:

Brain, right frontal lobe, biopsy #1: Glioma with astrocytic features.

Brain, right frontal lobe, excision #2: Hold over for permanent sections.

Brain, right frontal lobe, excision #3: Hold over for permanent sections.

Gross Description:

Source: NCI Genomic Data Commons file 8086f2a4-4742-4b2d-8bcd-830d4c33e148 (TCGA-15-1446.B04E9D08-F0BF-4A18-B638-0E1E739787A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).